Gene-level copy-number profile of tumor specimen TCGA-2G-AAFR-01A from TCGA case TCGA-2G-AAFR, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 25.3 years (9,225 days).
Specimen TCGA-2G-AAFR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a78232e2-38c9-43f0-8c7f-f11f40ee02c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAFR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/37fd062c-4833-4323-89ef-972fc0c89af7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,709; copy number 2: 27,923; copy number 3: 21,282; copy number 4: 5,266; copy number 5: 1,264; copy number 6: 589; copy number 7: 819; copy number 10: 38.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,635,091, 8 genes (within-gene range 0–1): AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr9:39,886,861–39,892,895, 3 genes: RN7SL763P, SNORA70, CR769767.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,710 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–154,351,304, 482 genes, copy number 5 (broad region; genes not listed).
- chr7:37,032–19,002,416, 298 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:58,814,412–58,814,552, 1 gene, copy number 5: RNU4-50P.
- chr8:69,466,624–70,669,185, 28 genes, copy number 5: SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P.
- chr8:144,373,101–144,475,849, 15 genes, copy number 5: ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1.
- chr12:66,767–39,467,345, 853 genes, copy number 6–7 (broad region; genes not listed).
- chr12:93,266,017–93,266,096, 1 gene, copy number 5: AC126172.1.
- chr14:18,667,249–18,945,139, 10 genes, copy number 6: CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2.
- chr14:22,415,362–22,465,787, 10 genes, copy number 5 (within-gene range 4–5): AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC.
- chr14:24,595,723–46,651,781, 286 genes, copy number 6–10 (broad region; genes not listed).
- chr19:11,559,374–11,619,161, 1 gene, copy number 5 (within-gene range 3–5): ZNF627.
- chr19:11,639,754–12,696,631, 79 genes, copy number 5 (broad region; genes not listed).
- chr19:18,306,236–38,636,955, 643 genes, copy number 5 (broad region; genes not listed).
- chr21:10,612,455–10,649,835, 3 genes, copy number 5: SLC25A15P4, AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 1,197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
